Somatic mutation profile of tumor specimen TARGET-50-PAKKNS-01A (aliquot TARGET-50-PAKKNS-01A-01D) from TARGET case TARGET-50-PAKKNS, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (547 days).
Specimen TARGET-50-PAKKNS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 542a5f7c-9fbb-4150-bdc4-d5e309e2b7a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKKNS-10A (Blood Derived Normal), aliquot TARGET-50-PAKKNS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bdad979-8bfd-4f91-83b2-a37de7188915

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ENPP6 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as COSV57066477; called by muse, mutect2, varscan2
- TTN | c.10663G>A p.G3555S (on ENST00000591111; = p.G3509S on NM_003319.4) | Missense Mutation (SNP) | VAF 135/274 reads (49%) | catalogued as rs754936734, COSV100593314, COSV59921041; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZFP82 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); called by muse, mutect2
